Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAGA, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAGA-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchidectomy; nonseminoma (EC 100%) diameter 2.3 cm; tumor confined to testis;
angio-invasion present; no invasion of rete testis.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

ICD O 3
Carcinoma, embryonal NOS
9070/3
R Testis NOS 062.9
9057/14

Source: NCI Genomic Data Commons file 21e9a2c8-78fc-4c76-a097-aecb75f3c609 (TCGA-2G-AAGA.51D17561-EFFD-460F-8AB7-CD6B121AAA21.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).